Somatic mutation profile of tumor specimen TCGA-JW-A69B-01A (aliquot TCGA-JW-A69B-01A-11D-A32I-09) from TCGA case TCGA-JW-A69B, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: GX; Age at diagnosis: 44.0 years (16,080 days).
Specimen TCGA-JW-A69B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 67530435-c42e-4026-96f9-d2b126106e84.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JW-A69B-10A (Blood Derived Normal), aliquot TCGA-JW-A69B-10A-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4888049c-d225-4f58-97f9-25ecaff75095

The open-access MAF lists 44 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 28, Silent 14, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 32/54 reads (59%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARHGAP45 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.972); catalogued as rs1192381664, COSV57431316; called by muse, mutect2, varscan2
- CPLANE2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1289066461, COSV65056593; called by muse, mutect2, varscan2
- CTNNA3 | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs372482202; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPP10 | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 13/31 reads (42%) | catalogued as COSV59682385; called by muse, mutect2, varscan2
- FH | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as rs778578307, COSV63817649; ClinVar: uncertain significance; called by muse, mutect2
- FOXG1 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV57396411; called by muse, mutect2, varscan2
- GAPVD1 | c.834T>G p.H278Q | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as COSV52922471; called by muse, mutect2, varscan2
- GLRA3 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.022); catalogued as rs774589195, COSV56860823; called by muse, mutect2, varscan2
- GOLGA3 | c.2350G>A p.A784T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV52629766; called by muse, mutect2, varscan2
- HEXB | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54667593; called by muse, mutect2, varscan2
- HSPB7 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.464); catalogued as rs561575565, COSV61307937; called by muse, mutect2, varscan2
- IFT22 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.31); PolyPhen benign (0.01); catalogued as rs1336139001, COSV59527125; called by muse, mutect2, varscan2
- KCNC3 | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65387243; called by muse, mutect2, varscan2
- KIFBP | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as COSV62831636; called by muse, mutect2, varscan2
- MAN1B1 | c.788G>A p.G263E | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65377916; called by muse, mutect2, varscan2
- MYH4 | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs768630081, COSV55113478; called by muse, mutect2, varscan2
- MYO9B | c.6367G>A p.A2123T | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as rs1261958560, COSV55727640; called by muse, mutect2, varscan2
- NKAIN2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs142309299; called by muse, mutect2, varscan2
- PCNX2 | c.4772T>C p.I1591T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV50796222; called by muse, mutect2, varscan2
- PNMA3 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV64722199; called by muse, mutect2, varscan2
- RAB33B | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59777329; called by muse, mutect2, varscan2
- RASAL3 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.038); catalogued as COSV52993196; called by muse, mutect2
- SDCBP | c.211G>T p.A71S | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV52705597; called by muse, mutect2, varscan2
- STX11 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV62449047; called by muse, mutect2, varscan2
- TOP3B | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs774264750, COSV64116920; called by muse, mutect2, varscan2
- TRPM5 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs748476202, COSV50150321; called by muse, mutect2, varscan2
- VEGFC | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.528); catalogued as COSV54597288; called by muse, mutect2, varscan2
- DDX20 | c.1752_1753insTAGCCATA p.Q585* | Nonsense Mutation (INS) | VAF 7/24 reads (29%) | called by mutect2, varscan2
- IGHA1 | c.972C>A p.F324L | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS2 | c.2271C>T p.D757= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs137875904; called by muse, mutect2, varscan2
- CCNB3 | c.576G>A p.K192= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as COSV52072604; called by muse, mutect2, varscan2
- CELSR3 | c.2226C>T p.V742= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV50851884, COSV51175448; called by muse, mutect2, varscan2
- COL18A1 | c.1422G>A p.T474= (on ENST00000359759 / NM_130444.3; = p.T239= on NM_030582.4) | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs779044009, COSV62700845; called by muse, mutect2, varscan2
- CTNNA2 | c.2028G>A p.P676= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs199921745, COSV58140359; called by muse, mutect2, varscan2
- FLNC | c.1650G>A p.T550= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs754474889, COSV57954944, COSV57957190; called by muse, mutect2, varscan2
- GIMAP1 | c.525C>T p.R175= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV56187952; called by muse, mutect2, varscan2
- GRXCR1 | c.114G>A p.P38= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs765148609, COSV67669715, COSV67671017; called by muse, varscan2
- HCN4 | c.639C>T p.F213= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs1555478937, COSV56083097; ClinVar: likely benign; called by muse, mutect2, varscan2
- IL7 | c.384C>T p.A128= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV55674332; called by muse, mutect2, varscan2
- L3MBTL2 | c.1443C>T p.S481= | Silent (SNP) | VAF 24/51 reads (47%) | catalogued as COSV53432911; called by muse, mutect2, varscan2
- MAN2A2 | c.2493C>T p.P831= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs373836101; called by muse, varscan2
- POMC | c.609C>T p.A203= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV53034765; called by muse, mutect2, varscan2
- SHC2 | c.1104C>A p.L368= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as COSV52745522; called by muse, mutect2
